Somatic mutation profile of tumor specimen ALCH-B3EH-TTP1-A (aliquot ALCH-B3EH-TTP1-A-2-0-D-A80C-36) from ALCHEMIST case ALCH-B3EH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.0 years (25,203 days).
Specimen ALCH-B3EH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ece7fc3-cba0-4aa1-bd21-632125e85935.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3EH-NB1-A (Blood Derived Normal), aliquot ALCH-B3EH-NB1-A-1-0-D-A80C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2045e21f-6047-4865-8e07-971f711c2436

The open-access MAF lists 60 somatic variants for this specimen: 43 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Intron 4, Nonsense Mutation 3, Splice Region 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 100/455 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, varscan2
- ADAMTS16 | c.355G>C p.V119L | Missense Mutation (SNP) | VAF 46/730 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as COSV56992025; called by muse, mutect2
- CHD3 | c.1336G>C p.E446Q | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV57874914; called by muse, mutect2
- DOCK8 | c.3952G>T p.D1318Y | Missense Mutation (SNP) | VAF 30/700 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1342441151, COSV101210138; called by muse, mutect2
- GPR32 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1568459841, COSV54513884; called by muse, mutect2
- GRM5 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 40/437 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776804851, COSV59590843; called by muse, mutect2
- KCNU1 | c.829G>A p.V277I | Missense Mutation (SNP) | VAF 43/707 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as rs368642765; called by muse, mutect2
- MLXIP | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 26/572 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV59834076; called by muse, mutect2
- NLRP3 | c.2434G>A p.G812R | Missense Mutation (SNP) | VAF 78/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1172036975, COSV100276624; called by muse, mutect2, varscan2
- OVOL2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs1334080185; called by muse, mutect2
- PATE3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs899482194; called by muse, mutect2
- REG1A | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 19/608 reads (3%) | catalogued as COSV52070688; called by muse, mutect2
- ZNF479 | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 42/752 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.339); catalogued as rs1554399792, COSV58637819, COSV58643680; called by muse, mutect2
- ACACA | c.3029A>G p.Q1010R | Missense Mutation (SNP) | VAF 58/740 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.399); called by muse, mutect2
- ARHGAP9 | c.1867G>A p.E623K (on ENST00000393797 / NM_001319850.2; = p.E604K on NM_032496.4) | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAMTA1 | c.2440T>C p.F814L | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); called by muse, mutect2
- CCDC168 | c.9494C>G p.S3165* | Nonsense Mutation (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- CCDC178 | c.2391C>G p.L797= (on ENST00000383096 / NM_001105528.3; = p.L759= on NM_198995.3) | Splice Region (SNP) | VAF 13/263 reads (5%) | called by muse, mutect2
- CENPB | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); called by muse, mutect2
- CUL3 | c.1709A>G p.E570G | Missense Mutation (SNP) | VAF 26/400 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- DNAH7 | c.2973G>T p.E991D | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GSE1 | c.1776C>A p.D592E | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.024); called by muse, mutect2
- KALRN | c.3456T>G p.F1152L | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.009); called by muse, mutect2
- MED17 | c.122C>G p.A41G | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2
- MUC12 | c.14891A>T p.E4964V (on ENST00000379442; = p.E4821V on NM_001164462.1) | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT deleterious (0); called by muse, mutect2
- MYH10 | c.4974A>T p.Q1658H | Missense Mutation (SNP) | VAF 26/610 reads (4%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); called by muse, mutect2
- NLRP12 | c.1410G>A p.W470* | Nonsense Mutation (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- OR8B3 | c.746C>G p.S249C | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2
- OSBPL8 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.01); called by muse, mutect2
- PER3 | c.969C>G p.H323Q | Missense Mutation (SNP) | VAF 22/604 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POLR3E | c.1178G>A p.R393K | Missense Mutation (SNP) | VAF 460/774 reads (59%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.702); called by muse, varscan2
- PPP2R5B | c.948G>A p.V316= | Splice Region (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- RRM2 | c.33C>G p.I11M | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); called by muse, mutect2
- RYR2 | c.4411G>A p.D1471N | Missense Mutation (SNP) | VAF 20/469 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2
- SALL1 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SCLT1 | c.1691G>A p.R564K | Missense Mutation (SNP) | VAF 22/645 reads (3%) | SIFT tolerated (0.7); PolyPhen benign (0.061); called by muse, mutect2
- SLC35D1 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 66/1099 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SP2 | c.331G>C p.V111L | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.284); called by muse, mutect2
- ST3GAL6 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 102/992 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.112); called by muse, mutect2
- TAF2 | c.3391C>T p.L1131F | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); called by muse, mutect2
- TRIM68 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 11/301 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TUBB4B | c.1188C>G p.H396Q | Missense Mutation (SNP) | VAF 31/450 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- ZBTB40 | c.1615G>C p.V539L | Missense Mutation (SNP) | VAF 38/716 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- CACNA1H | c.4641C>T p.L1547= | Silent (SNP) | VAF 12/111 reads (11%) | called by muse, mutect2, varscan2
- CAMKK1 | c.1095C>T p.I365= | Silent (SNP) | VAF 10/179 reads (6%) | catalogued as COSV50121786; called by muse, mutect2
- DDC | c.723C>T p.A241= | Silent (SNP) | VAF 129/729 reads (18%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13251G>C p.V4417= | Silent (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- MOSPD1 | c.519G>A p.L173= | Silent (SNP) | VAF 30/628 reads (5%) | called by muse, mutect2
- MPDZ | c.783G>A p.V261= | Silent (SNP) | VAF 16/507 reads (3%) | called by muse, mutect2
- NDUFA4 | c.18C>T p.I6= | Silent (SNP) | VAF 32/1043 reads (3%) | catalogued as COSV60011852; called by muse, mutect2
- NUBP1 | c.588G>A p.V196= | Silent (SNP) | VAF 11/213 reads (5%) | catalogued as COSV51594112; called by muse, mutect2
- POLR3E | c.1290G>A p.L430= | Silent (SNP) | VAF 283/456 reads (62%) | called by muse, mutect2, varscan2
- SPATA7 | c.1074C>A p.I358= | Silent (SNP) | VAF 44/1770 reads (2%) | called by muse, mutect2
- TGFBR2 | c.1515C>T p.L505= | Silent (SNP) | VAF 48/948 reads (5%) | called by muse, mutect2
- ZNF251 | c.1206G>A p.E402= | Silent (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- ADGRD1 | c.187+469C>T | Intron (SNP) | VAF 9/217 reads (4%) | catalogued as rs1344058966; called by muse, mutect2
- C8orf82 | c.157-237G>A | Intron (SNP) | VAF 4/39 reads (10%) | called by mutect2, varscan2
- ELMO2 | c.1884+178C>T | Intron (SNP) | VAF 10/196 reads (5%) | called by muse, mutect2
- SDHAP3 | n.129A>G | RNA (SNP) | VAF 96/1256 reads (8%) | called by muse, mutect2
- TSPAN31 | c.313-166G>A | Intron (SNP) | VAF 33/960 reads (3%) | catalogued as COSV57276002; called by muse, mutect2
